CPTAC case C3N-04098 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/51b21d04-1e46-4131-bbe4-40338731de99

Demographics
Sex at birth: female; Race: asian; Year of birth: 1955; Vital status: Dead; Days to death: 440 days (1.2 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 63.2 years (23,078 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 440 days (1.2 years); Days to last follow up: 440 days (1.2 years).
   Pathology details: Greatest tumor dimension: 4.5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Targeted Molecular Therapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 440 days (1.2 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 167 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 52 kg; Height: 159 cm; BMI: 20.57.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04098-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 120 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04098-21: Section location: Right Frontal and Parietal and Occipital Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-04098-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 90 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04098-22: Section location: Right Frontal and Parietal and Occipital Lobe; Percent tumor nuclei: 65; Percent necrosis: 10.
- Sample C3N-04098-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 5 days; Method of sample procurement: Blood Draw.
